Somatic mutation profile of tumor specimen HCM-CSHL-0094-C25-86A (aliquot HCM-CSHL-0094-C25-86A-01D-A78M-36) from HCMI case HCM-CSHL-0094-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.5 years (22,468 days).
Specimen HCM-CSHL-0094-C25-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f7a243-6fe3-497e-957e-195d25743a0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0094-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0094-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed279446-0b88-431e-9c16-ae577fc7ed1d

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Intron 3, 5'Flank 1, Frame Shift Ins 1, Translation Start Site 1, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 214/214 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 233/233 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753831464, COSV51941487; ClinVar: benign; called by muse, mutect2, varscan2
- DCAF12L2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 107/232 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.271); catalogued as COSV63580171; called by muse, mutect2, varscan2
- DCDC1 | c.4187C>T p.T1396M (on ENST00000597505 / NM_001367979.1; = p.T503M on NM_020869.3) | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs563373193, COSV58004873; called by muse, mutect2, varscan2
- EIF2AK4 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV55471934; called by muse, varscan2
- FZD10 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 61/62 reads (98%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV57473678, COSV99969588; called by muse, mutect2, varscan2
- LNX1 | c.1393C>T p.R465W (on ENST00000263925 / NM_001126328.3; = p.R369W on NM_032622.2) | Missense Mutation (SNP) | VAF 102/150 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs753035872, COSV55784766; called by muse, mutect2, varscan2
- MYH4 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.44); catalogued as rs185824725; called by muse, mutect2, varscan2
- PCDH18 | c.981A>T p.Q327H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61266332, COSV61268397; called by muse, mutect2, varscan2
- PCDHA3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 293/293 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.435); catalogued as COSV100793689; called by muse, mutect2, varscan2
- PDCD6IP | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs752951471; called by muse, mutect2, varscan2
- PLCG2 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368889160; called by muse, mutect2, varscan2
- PRKCE | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 103/334 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100077197; called by muse, mutect2, varscan2
- PTCH2 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.552); catalogued as rs377325413; called by muse, mutect2, varscan2
- RTL3 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 79/392 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58183628; called by muse, mutect2, varscan2
- SYNE1 | c.12122G>A p.R4041Q (on ENST00000367255 / NM_182961.4; = p.R3970Q on NM_033071.3) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as rs771461121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.3307G>A p.V1103M (on ENST00000367255 / NM_182961.4; = p.V1110M on NM_033071.3) | Missense Mutation (SNP) | VAF 303/304 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1229856716, COSV54929914; called by muse, mutect2, varscan2
- TUT1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 119/197 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs746824330; called by muse, mutect2, varscan2
- ZP3 | c.532G>A p.E178K (on ENST00000394857 / NM_001110354.2; = p.E127K on NM_007155.6) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV60631483; called by muse, mutect2
- ACSBG1 | c.1823C>G p.S608C | Missense Mutation (SNP) | VAF 139/538 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.178); called by muse, varscan2
- CDKN2A | c.379dup p.A127Gfs*15 | Frame Shift Ins (INS) | VAF 313/435 reads (72%) | called by mutect2, pindel, varscan2
- CNTN2 | c.2434C>T p.P812S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH7 | c.7488T>G p.C2496W | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXOSC7 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 183/305 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- EXOSC8 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 117/237 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- HOXA4 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IER5 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 145/202 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MBD6 | c.2873+1G>T p.X958_splice | Splice Site (SNP) | VAF 121/203 reads (60%) | called by muse, mutect2, varscan2
- PAQR5 | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 126/186 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- PIAS1 | c.436T>A p.L146I | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, varscan2
- PRAMEF15 | c.1017T>A p.S339R | Missense Mutation (SNP) | VAF 301/949 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- RNF43 | c.405_406insCGCGGGTGAGCGAGGAGCCAGT p.A136Rfs*3 | Nonsense Mutation (INS) | VAF 20/26 reads (77%) | called by mutect2, pindel
- SEMA6D | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGFBR1 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ACTR3C | c.111A>G p.T37= | Silent (SNP) | VAF 19/176 reads (11%) | catalogued as rs916981079; called by muse, mutect2, varscan2
- AGPAT1 | c.423G>A p.L141= | Silent (SNP) | VAF 433/442 reads (98%) | catalogued as rs780934272; called by muse, mutect2, varscan2
- IRGC | c.1185C>T p.D395= | Silent (SNP) | VAF 175/255 reads (69%) | catalogued as rs142781236; called by muse, mutect2, varscan2
- MKRN3 | c.456G>A p.P152= | Silent (SNP) | VAF 101/335 reads (30%) | catalogued as rs536725835, COSV100091899; called by muse, mutect2, varscan2
- NLRP4 | c.657C>A p.I219= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs754739238, COSV56711965; called by muse, mutect2, varscan2
- OR5D16 | c.669C>T p.I223= | Silent (SNP) | VAF 63/191 reads (33%) | called by muse, mutect2, varscan2
- PCDH15 | c.4950G>A p.S1650= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as rs755469136; called by muse, mutect2
- PGPEP1L | c.300C>T p.V100= | Silent (SNP) | VAF 19/632 reads (3%) | called by muse, mutect2
- RMC1 | c.831G>C p.V277= | Silent (SNP) | VAF 47/47 reads (100%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1278C>T p.G426= (on ENST00000621492; = p.G392= on NM_025248.3) | Silent (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- TNRC18 | c.1581C>T p.A527= | Silent (SNP) | VAF 269/500 reads (54%) | catalogued as rs1221834058; called by muse, mutect2, varscan2
- ZWINT | c.741G>A p.Q247= | Silent (SNP) | VAF 21/196 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915952 G>A | 5'Flank (SNP) | VAF 94/159 reads (59%) | called by muse, mutect2, varscan2
- ATXN7 | c.2661+1151C>T | Intron (SNP) | VAF 115/175 reads (66%) | called by muse, mutect2, varscan2
- CD22 | c.-6G>A | 5'UTR (SNP) | VAF 74/280 reads (26%) | catalogued as rs374673200; called by muse, mutect2, varscan2
- FTCD | c.1261-39T>C | Intron (SNP) | VAF 127/208 reads (61%) | called by muse, mutect2, varscan2
- SLC2A11 | c.537-272C>T | Intron (SNP) | VAF 80/153 reads (52%) | catalogued as rs756171416; called by muse, mutect2, varscan2
